Somatic mutation profile of tumor specimen TCGA-RT-A6Y9-01A (aliquot TCGA-RT-A6Y9-01A-12D-A35D-08) from TCGA case TCGA-RT-A6Y9, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 50.9 years (18,594 days).
Specimen TCGA-RT-A6Y9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac771e52-17d8-4e57-b7f2-c5957bacd83e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RT-A6Y9-10B (Blood Derived Normal), aliquot TCGA-RT-A6Y9-10B-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67b18ad1-83af-430d-8e10-06bc6ff8692a

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A4 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs935822119, COSV63626205; called by muse, mutect2, varscan2
- HDLBP | c.1523G>C p.R508P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV60501555, COSV60501962; called by muse, mutect2, varscan2
- SLC20A1 | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.043); catalogued as rs191761952; called by muse, mutect2, varscan2
- NCOA3 | c.3302C>T p.A1101V | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.097); called by muse, mutect2
- STAG2 | c.320dup p.H108Afs*2 | Frame Shift Ins (INS) | VAF 41/113 reads (36%) | called by mutect2, pindel, varscan2
- PRRC2B | c.5064G>A p.Q1688= | Silent (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
